Somatic mutation profile of tumor specimen TCGA-A2-A259-01A (aliquot TCGA-A2-A259-01A-11D-A16D-09) from TCGA case TCGA-A2-A259, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 70.3 years (25,666 days).
Specimen TCGA-A2-A259-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 352d0461-1f62-4009-a73f-4aaa9b729d12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A259-10A (Blood Derived Normal), aliquot TCGA-A2-A259-10A-01D-A16D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73d978ac-bb77-4ff0-b21b-edfec2301bf4

The open-access MAF lists 24 somatic variants for this specimen: 21 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3, Frame Shift Del 2, Nonsense Mutation 2, In Frame Del 1, Frame Shift Ins 1, Nonstop Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- WDR72 | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 15/72 reads (21%) | catalogued as rs770804941, COSV64751166; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRF1 | c.2435T>G p.V812G | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV51946849; called by muse, mutect2, varscan2
- AFF2 | c.2668C>T p.H890Y | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV54000115; called by muse, mutect2, varscan2
- CEP70 | c.146G>A p.R49K | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as rs1250694077, COSV53877264; called by muse, mutect2, varscan2
- CLEC17A | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 49/245 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs368206109; called by muse, mutect2, varscan2
- HERC1 | c.13205_13214del p.R4402Pfs*14 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | catalogued as COSV71249419; called by mutect2, pindel
- ILF3 | c.188A>G p.D63G | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV51560787; called by muse, mutect2, varscan2
- KMT2C | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 47/195 reads (24%) | catalogued as COSV51449755; called by muse, mutect2, varscan2
- MAP3K1 | c.4155_4180del p.I1386Vfs*25 | Frame Shift Del (DEL) | VAF 30/148 reads (20%) | catalogued as COSV68125810; called by mutect2, pindel
- MAP3K1 | c.4298G>C p.W1433S | Missense Mutation (SNP) | VAF 35/214 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68125817; called by muse, mutect2, varscan2
- NONO | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV52139306; called by muse, mutect2, varscan2
- NUP88 | c.2225G>C p.*742Sext*9 | Nonstop Mutation (SNP) | VAF 23/226 reads (10%) | catalogued as COSV52586907; called by muse, varscan2
- NUP88 | c.1836G>A p.R612= | Splice Region (SNP) | VAF 12/126 reads (10%) | catalogued as COSV99337023; called by muse, varscan2
- OSBPL11 | c.478G>C p.A160P | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.862); catalogued as COSV56175517; called by muse, mutect2, varscan2
- RABEP1 | c.2578C>G p.P860A | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV52586904; called by muse, mutect2, varscan2
- RPS5 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as COSV52191477; called by muse, mutect2, varscan2
- SLC4A10 | c.2806C>T p.P936S (on ENST00000446997 / NM_001354461.2; = p.P906S on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/292 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55791295; called by muse, mutect2, varscan2
- TMEM214 | c.539G>A p.G180E | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.274); catalogued as COSV53193455; called by muse, mutect2
- WDFY2 | c.1076C>T p.T359I | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs766279668, COSV53291721; called by muse, varscan2
- SIN3A | c.3068_3085del p.L1023_N1029delinsH | In Frame Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, pindel, varscan2
- SLC43A2 | c.521_528dup p.S177Tfs*9 | Frame Shift Ins (INS) | VAF 13/37 reads (35%) | called by mutect2, varscan2
- PLXNA3 | c.3918G>T p.V1306= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs782419059, COSV63754995; called by muse, mutect2, varscan2
- VAV2 | c.414C>T p.D138= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as rs374653028; called by muse, mutect2, varscan2
- ZHX2 | c.996G>A p.K332= | Silent (SNP) | VAF 36/55 reads (65%) | catalogued as COSV58715401; called by muse, mutect2, varscan2
